Somatic mutation profile of tumor specimen TCGA-90-A4ED-01A (aliquot TCGA-90-A4ED-01A-31D-A257-08) from TCGA case TCGA-90-A4ED, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 69.7 years (25,453 days).
Specimen TCGA-90-A4ED-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dac4d351-7a44-4590-8244-f7b93e7330e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-90-A4ED-10A (Blood Derived Normal), aliquot TCGA-90-A4ED-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c265d468-73aa-48a0-a208-e2b74a733f2c

The open-access MAF lists 2,384 somatic variants for this specimen: 1,506 protein-altering or splice-affecting, 820 silent, 58 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,383, Silent 820, Nonsense Mutation 74, Splice Region 22, Intron 20, RNA 19, Splice Site 15, 5'UTR 9, Translation Start Site 6, 3'UTR 5, Frame Shift Del 4, 5'Flank 3.

Variants (750 of 2,384; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTB | c.1013C>T p.S338F | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1554329113, COSV100079965; ClinVar: likely pathogenic; called by muse, varscan2
- ATM | c.7181C>T p.S2394L | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as rs587779861, CM083481, COSV53735356, COSV53772240; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SCNN1B | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 105/271 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852710, CM056055, COSV100226076; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.590G>T p.R197M | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99258179; called by muse, mutect2, varscan2
- AADACL3 | c.1216G>A p.G406R | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.16); catalogued as COSV100206924, COSV60198650; called by muse, mutect2, varscan2
- AARS2 | c.2942C>T p.A981V | Missense Mutation (SNP) | VAF 73/252 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as COSV99771445; called by muse, mutect2, varscan2
- ABCA10 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99289449; called by muse, mutect2, varscan2
- ABO | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.79); PolyPhen benign (0.011); catalogued as rs1554758190, COSV71743681; called by muse, mutect2, varscan2
- AC006059.2 | c.2040G>A p.M680I | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100046034; called by muse, mutect2, varscan2
- ACD | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.013); catalogued as COSV54665920, COSV99538042; called by muse, mutect2, varscan2
- ACER1 | c.337C>T p.L113F | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.628); catalogued as COSV100034142; called by muse, mutect2, varscan2
- ACSM1 | c.1241G>A p.G414E | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs867105850, COSV54635549; called by muse, mutect2, varscan2
- ACTL7A | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.082); catalogued as rs139566194, COSV100453244; called by muse, mutect2, varscan2
- ADAM18 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV55845381; called by muse, mutect2, varscan2
- ADAM19 | c.863A>G p.K288R | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV99978678; called by muse, mutect2
- ADAM29 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.214); catalogued as COSV100822290; called by muse, mutect2, varscan2
- ADAM32 | c.1478G>A p.G493E | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65953070; called by muse, mutect2, varscan2
- ADAMTS12 | c.4177G>A p.D1393N | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV100710675, COSV100711757, COSV61279065; called by muse, mutect2, varscan2
- ADAMTS13 | c.1308G>A p.Q436= | Splice Region (SNP) | VAF 23/85 reads (27%) | catalogued as CM129657, CS126173, COSV63021548; called by muse, mutect2, varscan2
- ADAMTS14 | c.1132C>T p.P378S | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as rs1418535072, COSV64603654; called by muse, mutect2, varscan2
- ADAMTS14 | c.1133C>T p.P378L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.329); catalogued as rs1276604797, COSV100941918; called by muse, mutect2, varscan2
- ADAMTS17 | c.1978C>T p.P660S | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.941); catalogued as rs879133196, COSV99171864; called by muse, mutect2, varscan2
- ADAMTS9 | c.5774C>T p.S1925F | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as rs1364561624, COSV99900364; called by muse, mutect2, varscan2
- ADAR | c.3509C>T p.S1170F | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99426858; called by muse, mutect2, varscan2
- ADARB1 | c.1940C>T p.S647F (on ENST00000360697 / NM_001346687.2; = p.S607F on NM_001112.4) | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.285); catalogued as COSV100654165; called by muse, mutect2, varscan2
- ADCY5 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.026); catalogued as COSV101518466; called by muse, mutect2, varscan2
- ADCY8 | c.1568G>T p.R523M | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV53929947, COSV99654758; called by muse, mutect2, varscan2
- ADGRB3 | c.1062G>A p.W354* | Nonsense Mutation (SNP) | VAF 49/147 reads (33%) | catalogued as COSV101002042; called by muse, mutect2, varscan2
- ADGRE1 | c.1043C>T p.S348F | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1366583656, COSV51672721, COSV99165755; called by muse, mutect2, varscan2
- ADGRF4 | c.1632G>A p.M544I | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV99349123; called by muse, mutect2, varscan2
- ADGRV1 | c.10007C>T p.S3336F | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as rs781697491, COSV67998208; called by muse, mutect2
- ADRA1B | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100140509; called by muse, mutect2, varscan2
- AFG3L2 | c.1474C>T p.R492* | Nonsense Mutation (SNP) | VAF 26/82 reads (32%) | catalogued as rs753902034, COSV99301548; called by muse, mutect2, varscan2
- AFP | c.1267G>A p.G423R | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99890454; called by muse, mutect2, varscan2
- AGBL1 | c.1289C>T p.S430F | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as COSV101224371; called by muse, mutect2, varscan2
- AGL | c.2351G>A p.R784K | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as COSV99650166; called by muse, mutect2, varscan2
- AGTR1 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV100836918, COSV100837216; called by muse, mutect2, varscan2
- AHNAK2 | c.10081C>T p.P3361S | Missense Mutation (SNP) | VAF 37/232 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.359); catalogued as COSV60933927; called by muse, mutect2, varscan2
- AIFM2 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.468); catalogued as rs752400502, COSV57158868; called by muse, mutect2, varscan2
- AJM1 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.306); catalogued as COSV99915943; called by muse, mutect2, varscan2
- AKAP6 | c.2222C>T p.S741L | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV99805076; called by muse, mutect2, varscan2
- AKR1D1 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.382); catalogued as rs1457496759, COSV54338463; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKT1S1 | c.425C>T p.P142L (on ENST00000344175 / NM_001098633.4; = p.P162L on NM_032375.5) | Missense Mutation (SNP) | VAF 52/236 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV100465755; called by muse, mutect2, varscan2
- ALB | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs78575701, CM984718, COSV104405337, COSV55736801, COSV55738814; ClinVar: not provided; called by muse, mutect2, varscan2
- ALDOB | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100878943; called by muse, mutect2, varscan2
- ALK | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 43/190 reads (23%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as rs145681577; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALMS1 | c.6034C>T p.P2012S | Missense Mutation (SNP) | VAF 66/201 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.233); catalogued as COSV100043996, COSV52522603; called by muse, mutect2, varscan2
- ALOX5 | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 17/64 reads (27%) | catalogued as rs1161695683, COSV100980133; called by muse, mutect2, varscan2
- AMPH | c.898G>A p.G300R | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57741373; called by muse, mutect2, varscan2
- AMY1C | c.955G>A p.G319R | Missense Mutation (SNP) | VAF 56/305 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100915249; called by muse, mutect2, varscan2
- ANGPTL5 | c.296G>A p.R99K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.021); catalogued as COSV100527735; called by muse, mutect2, varscan2
- ANGPTL6 | c.1376G>A p.R459K | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99464039; called by muse, varscan2
- ANK1 | c.4666G>A p.E1556K | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.14); catalogued as COSV99227155; called by muse, mutect2, varscan2
- ANK2 | c.9913C>T p.P3305S | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as COSV52144641; called by muse, mutect2, varscan2
- ANK2 | c.10169C>T p.S3390F | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100004595, COSV52173555; called by muse, mutect2, varscan2
- ANKAR | c.3967G>A p.E1323K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as COSV99854777; called by muse, mutect2, varscan2
- ANKFY1 | c.2141C>T p.A714V (on ENST00000341657 / NM_001330063.2; = p.A715V on NM_016376.5) | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100493234; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3869C>T p.S1290F | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51842737, COSV99784714; called by muse, mutect2, varscan2
- ANKLE1 | c.1400C>T p.A467V (on ENST00000394458; = p.A413V on NM_152363.6) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs762892589, COSV100845790; called by muse, mutect2, varscan2
- ANKMY1 | c.713A>G p.N238S | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.144); catalogued as COSV99803457; called by muse, mutect2, varscan2
- ANTKMT | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.038); catalogued as rs201512651; called by muse, mutect2, varscan2
- ANTXR2 | c.1347G>T p.K449N | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100227036; called by mutect2, varscan2
- ANXA6 | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62905512; called by muse, mutect2, varscan2
- ANXA7 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.247); catalogued as COSV100873524; called by muse, mutect2, varscan2
- AOC1 | c.2167C>T p.P723S | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV100711033; called by muse, mutect2, varscan2
- AOX1 | c.2872G>A p.E958K | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as rs989025504, COSV65980339; called by muse, mutect2, varscan2
- AP002512.3 | c.952C>T p.L318F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.315); catalogued as COSV54405649, COSV99688163; called by muse, mutect2, varscan2
- APLNR | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99951701; called by muse, mutect2, varscan2
- APOA4 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 104/323 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.701); catalogued as rs145184607; called by muse, mutect2, varscan2
- APOB | c.7054C>T p.Q2352* | Nonsense Mutation (SNP) | VAF 14/69 reads (20%) | catalogued as COSV99268558; called by muse, mutect2, varscan2
- ARFGEF3 | c.5363C>T p.P1788L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV99294878; called by muse, mutect2, varscan2
- ARHGAP33 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs752018639, COSV50123932; called by muse, mutect2, varscan2
- ARHGEF17 | c.5701C>T p.P1901S | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV99737017; called by muse, mutect2, varscan2
- ARID2 | c.1538C>T p.P513L | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV100537159; called by muse, mutect2, varscan2
- ARID3B | c.1060C>T p.L354F | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV100654784; called by muse, mutect2, varscan2
- ARL6IP5 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.999); catalogued as COSV99833056; called by muse, mutect2, varscan2
- ARPC3 | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.89); catalogued as COSV99959611; called by muse, mutect2, varscan2
- ARPC3 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.406); catalogued as COSV99959613; called by muse, mutect2, varscan2
- ART4 | c.634C>T p.L212F | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.315); catalogued as rs921611999, COSV99967012; called by muse, mutect2, varscan2
- ARV1 | c.298C>T p.H100Y | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.898); catalogued as COSV100048658; called by muse, mutect2, varscan2
- ASAH1 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0.249); catalogued as COSV100026028, COSV50501754; called by muse, mutect2, varscan2
- ASB11 | c.681G>A p.W227* | Nonsense Mutation (SNP) | VAF 29/46 reads (63%) | catalogued as COSV100729180; called by muse, mutect2, varscan2
- ASB5 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773072886, COSV99642192; called by muse, mutect2, varscan2
- ASH1L | c.811A>G p.I271V | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as COSV100853620; called by muse, mutect2, varscan2
- ASPM | c.10340C>T p.P3447L | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as rs751670703; called by mutect2, varscan2
- ATP10B | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.373); catalogued as COSV100469882; called by muse, mutect2, varscan2
- ATP11A | c.3343C>T p.L1115F | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.081); catalogued as COSV52119097; called by muse, mutect2, varscan2
- ATP6V0C | c.380T>C p.L127P | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99566237; called by muse, mutect2, varscan2
- ATP6V1B2 | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV99369628; called by mutect2, varscan2
- ATP6V1H | c.1012C>T p.L338F | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs868062866, COSV100778595, COSV100778885; called by muse, mutect2, varscan2
- ATR | c.1571C>T p.S524F | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.005); catalogued as COSV100638667; called by muse, mutect2, varscan2
- ATRN | c.2084C>T p.S695F | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV53533961; called by muse, mutect2, varscan2
- ATXN1 | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.079); catalogued as COSV99788121; called by muse, mutect2
- BAG6 | c.2267C>T p.S756F (on ENST00000676571; = p.S709F on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52994719; called by muse, mutect2, varscan2
- BAHCC1 | c.6881C>T p.P2294L | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.06); PolyPhen benign (0.274); catalogued as rs1215229479, COSV57029098; called by muse, mutect2, varscan2
- BAZ2B | c.1574C>T p.A525V | Missense Mutation (SNP) | VAF 56/207 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV58612642; called by muse, mutect2, varscan2
- BCAN | c.1060C>T p.R354* | Nonsense Mutation (SNP) | VAF 62/189 reads (33%) | catalogued as rs749412358, COSV100227796; called by muse, mutect2, varscan2
- BCHE | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as COSV52254114; called by muse, mutect2, varscan2
- BCL2L13 | c.385C>T p.Q129* | Nonsense Mutation (SNP) | VAF 15/65 reads (23%) | catalogued as COSV100456441; called by muse, mutect2, varscan2
- BEND3 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.039); catalogued as COSV100944709; called by muse, mutect2, varscan2
- BEST1 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as rs765385264, COSV57120026; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BEST2 | c.1088C>T p.S363F | Missense Mutation (SNP) | VAF 58/195 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99244719; called by muse, mutect2, varscan2
- BIRC6 | c.4612C>T p.L1538F | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.682); catalogued as COSV101428082, COSV101429134; called by muse, mutect2, varscan2
- BLM | c.2422C>T p.R808C | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759330541, COSV61922418; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMP1 | c.2746G>A p.D916N | Missense Mutation (SNP) | VAF 75/181 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.523); catalogued as rs764118980, COSV60529402; called by muse, mutect2, varscan2
- BMP10 | c.994T>C p.F332L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99770662; called by muse, mutect2, varscan2
- BMP10 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs748398969, COSV99770664; called by muse, mutect2, varscan2
- BPGM | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.345); catalogued as COSV100790235; called by muse, mutect2, varscan2
- BPIFB4 | c.1771C>T p.P591S | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64951329; called by muse, mutect2, varscan2
- BPIFB6 | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs202105575, COSV62754954; called by muse, mutect2, varscan2
- BRAF | c.2293C>T p.H765Y (on ENST00000288602 / NM_001374244.1; = p.H725Y on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56163967; called by muse, mutect2, varscan2
- BRD2 | c.313G>T p.A105S | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100875864; called by muse, mutect2, varscan2
- BRD7 | c.1039G>A p.G347R | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101165079; called by muse, mutect2, varscan2
- BRINP3 | c.1222C>T p.L408F | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100819582; called by muse, mutect2, varscan2
- BTF3 | c.409C>T p.H137Y (on ENST00000380591 / NM_001037637.1; = p.H93Y on NM_001207.4) | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV100246744; called by muse, mutect2, varscan2
- C10orf120 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.728); catalogued as COSV61492883; called by muse, mutect2, varscan2
- C11orf1 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99500427; called by muse, mutect2, varscan2
- C12orf66 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV61323122; called by muse, mutect2
- C12orf66 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.756); catalogued as COSV100320938; called by muse, mutect2
- C16orf46 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 64/131 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs138763234; called by muse, mutect2, varscan2
- C16orf72 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV100589141; called by muse, mutect2, varscan2
- C19orf25 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753472578, COSV99961106; called by muse, mutect2, varscan2
- C19orf25 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99961107; called by muse, mutect2, varscan2
- C1orf116 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV100848037; called by muse, mutect2, varscan2
- C1orf216 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs563604914, COSV52049049; called by muse, mutect2, varscan2
- C3 | c.4817G>A p.G1606D | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1431337479, COSV99837382; called by muse, mutect2, varscan2
- C5 | c.3409G>A p.A1137T | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV99798937; called by muse, mutect2, varscan2
- C5 | c.3408A>T p.E1136D | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV99798942; called by muse, mutect2, varscan2
- C5AR1 | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV61892288; called by muse, mutect2, varscan2
- C7 | c.1466G>A p.G489E | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100496710; called by muse, mutect2, varscan2
- C9orf24 | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1290269225, COSV99898157; called by muse, mutect2, varscan2
- CA11 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.676); catalogued as COSV99320900; called by muse, mutect2, varscan2
- CABP5 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1380996642, COSV99506579, COSV99506757; called by muse, mutect2, varscan2
- CACNA1H | c.6580G>A p.V2194M | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV99327157; called by muse, mutect2, varscan2
- CACNA1S | c.104C>T p.T35I | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV100755434; called by muse, mutect2, varscan2
- CACNA2D1 | c.971A>T p.N324I | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.74); catalogued as COSV100667556; called by muse, mutect2, varscan2
- CACNA2D1 | c.322C>T p.Q108* | Nonsense Mutation (SNP) | VAF 69/253 reads (27%) | catalogued as rs1554442334, COSV62385503, COSV62387509; called by muse, mutect2, varscan2
- CACNB2 | c.916G>A p.D306N (on ENST00000324631 / NM_201596.3; = p.D251N on NM_000724.4) | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV56636131, COSV99996793; called by muse, mutect2, varscan2
- CADM3 | c.778C>T p.P260S (on ENST00000368125 / NM_001127173.3; = p.P294S on NM_021189.5) | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100930430; called by muse, mutect2, varscan2
- CALCA | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs782292234, COSV100524130, COSV100524134; called by muse, mutect2, varscan2
- CALHM5 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 53/187 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.116); catalogued as rs539288012, COSV100635512; called by muse, mutect2, varscan2
- CAND1 | c.3362T>G p.M1121R | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV101607361; called by muse, mutect2, varscan2
- CARD18 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT tolerated (0.85); PolyPhen benign (0.326); catalogued as COSV101596041; called by muse, mutect2, varscan2
- CATSPERD | c.1412C>T p.S471F | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100486984; called by muse, mutect2
- CATSPERD | c.2086C>T p.P696S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58468007; called by muse, mutect2, varscan2
- CATSPERD | c.2087C>T p.P696L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752543668, COSV58465975; called by muse, mutect2, varscan2
- CBLIF | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1347451986, COSV99951113; called by muse, mutect2, varscan2
- CBLL1 | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 73/307 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.408); catalogued as rs765850580, COSV99756011; called by muse, mutect2, varscan2
- CCDC102B | c.67A>T p.I23F | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.116); catalogued as COSV100105128; called by muse, mutect2, varscan2
- CCDC102B | c.806A>T p.K269I | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100105130; called by muse, mutect2, varscan2
- CCDC181 | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.159); catalogued as rs530288123, COSV63155897; called by muse, mutect2
- CCDC63 | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.372); catalogued as COSV100370666; called by muse, mutect2, varscan2
- CCDC7 | c.2393C>T p.S798L | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV100179397; called by muse, mutect2, varscan2
- CCDC88A | c.5075A>G p.K1692R (on ENST00000436346 / NM_001365480.1; = p.K1664R on NM_018084.5) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1000027740, COSV99711316; called by muse, mutect2, varscan2
- CCDC88A | c.3988C>T p.Q1330* | Nonsense Mutation (SNP) | VAF 17/53 reads (32%) | catalogued as COSV99711319; called by muse, mutect2, varscan2
- CCER1 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 134/408 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV100727178; called by muse, varscan2
- CCER1 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 59/202 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.827); catalogued as rs1217974460, COSV62646293; called by muse, varscan2
- CCL24 | c.209G>A p.G70D | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as rs955446524, COSV99768896; called by muse, mutect2, varscan2
- CCNF | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99564271; called by muse, mutect2, varscan2
- CCNK | c.558G>A p.W186* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as COSV101110539; called by muse, mutect2, varscan2
- CCR3 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as COSV100656808; called by muse, mutect2, varscan2
- CCT6B | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.635); catalogued as rs567919309, COSV58490811; called by muse, mutect2, varscan2
- CCT8L2 | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 55/222 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs371551453; called by muse, mutect2, varscan2
- CD163 | c.1607G>A p.G536E | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63131336; called by muse, mutect2, varscan2
- CD1A | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.052); catalogued as rs201755458, COSV99192638; called by muse, mutect2, varscan2
- CD207 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368757763, COSV101338602, COSV69652776; called by muse, mutect2, varscan2
- CD22 | c.1912C>T p.P638S | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.193); catalogued as rs745341857, COSV99323128; called by muse, mutect2, varscan2
- CD2AP | c.1529C>T p.S510F | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV100830679; called by muse, mutect2
- CD2BP2 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.36); catalogued as COSV99977268; called by muse, mutect2, varscan2
- CD2BP2 | c.544G>A p.G182R | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.049); catalogued as COSV59769517, COSV99977270; called by muse, mutect2, varscan2
- CD300LG | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 118/189 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53223867; called by muse, mutect2, varscan2
- CD34 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100178732; called by muse, mutect2, varscan2
- CD5 | c.706C>T p.Q236* | Nonsense Mutation (SNP) | VAF 28/79 reads (35%) | catalogued as COSV61717775; called by muse, mutect2, varscan2
- CD93 | c.1504C>T p.P502S | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV99849676; called by muse, mutect2, varscan2
- CDADC1 | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.726); catalogued as COSV99212586, COSV99212620; called by muse, mutect2, varscan2
- CDC42EP3 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54874388; called by muse, mutect2, varscan2
- CDC6 | c.676T>C p.F226L | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.029); catalogued as COSV99266712; called by muse, mutect2, varscan2
- CDCA7 | c.692C>T p.S231L (on ENST00000347703 / NM_145810.3; = p.S310L on NM_031942.5) | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.355); catalogued as rs1281948661, COSV100143754, COSV60719943; called by muse, mutect2, varscan2
- CDH10 | c.2287del p.D763Ifs*13 | Frame Shift Del (DEL) | VAF 40/179 reads (22%) | catalogued as COSV52577289; called by mutect2, pindel, varscan2
- CDH12 | c.2228G>A p.G743E | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781251474, COSV101203420; called by muse, mutect2, varscan2
- CDH18 | c.2036C>T p.P679L | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.048); catalogued as COSV56923727; called by muse, varscan2
- CDH2 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52290491; called by muse, mutect2, varscan2
- CDH23 | c.2971G>A p.E991K | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); catalogued as rs551073659, COSV99819789; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1865C>T p.S622L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV100575061; called by muse, mutect2
- CDKL3 | c.1232C>T p.P411L | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99528216; called by muse, mutect2, varscan2
- CDON | c.352C>A p.L118I | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.279); catalogued as COSV99701263; called by muse, mutect2, varscan2
- CDX4 | c.651G>A p.V217= | Splice Region (SNP) | VAF 9/14 reads (64%) | catalogued as rs1569494381, COSV100999164; called by muse, mutect2, varscan2
- CEACAM20 | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.387); catalogued as COSV100387054; called by muse, mutect2, varscan2
- CEACAM3 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 60/314 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as rs782093115, COSV104381561, COSV55763529; called by muse, mutect2, varscan2
- CEL | c.1715C>T p.T572I (on ENST00000673714; = p.T569I on NM_001807.6) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV100672893; called by muse, varscan2
- CELSR3 | c.7217C>T p.S2406F | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.652); catalogued as rs1394275445, COSV50843611, COSV99375268; called by muse, mutect2, varscan2
- CEMIP2 | c.3844C>T p.P1282S | Missense Mutation (SNP) | VAF 92/243 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.387); catalogued as COSV100987534; called by muse, mutect2, varscan2
- CENPT | c.993A>T p.E331D | Missense Mutation (SNP) | VAF 141/246 reads (57%) | SIFT tolerated (0.59); PolyPhen benign (0.277); catalogued as COSV99535401; called by muse, mutect2, varscan2
- CEP120 | c.1912C>T p.P638S | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1224640988, COSV100071536; called by muse, varscan2
- CEP250 | c.4018C>T p.Q1340* | Nonsense Mutation (SNP) | VAF 29/104 reads (28%) | catalogued as COSV100699240; called by muse, mutect2, varscan2
- CES2 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781686511, COSV100399464; called by muse, mutect2, varscan2
- CFAP45 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.652); catalogued as COSV100928682; called by muse, mutect2, varscan2
- CFAP46 | c.6267G>A p.Q2089= | Splice Region (SNP) | VAF 5/36 reads (14%) | catalogued as COSV99585692; called by muse, mutect2
- CFAP52 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100235653; called by muse, mutect2, varscan2
- CFAP54 | c.8099A>G p.Y2700C | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.976); catalogued as COSV100733413; called by muse, mutect2, varscan2
- CFAP65 | c.3509G>A p.R1170K | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV100446046; called by muse, mutect2, varscan2
- CFAP65 | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.023); catalogued as rs544739894, COSV55390092; called by muse, mutect2, varscan2
- CFAP65 | c.481G>A p.E161K (on ENST00000341552 / NM_194302.4; = p.E96K on NM_152389.4) | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771832922, COSV99838508; called by muse, mutect2, varscan2
- CFAP70 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV100161135; called by muse, mutect2, varscan2
- CFAP94 | c.137T>A p.I46K (on ENST00000320267 / NM_001352064.2; = p.I52K on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100209803; called by muse, mutect2, varscan2
- CFH | c.3523G>A p.E1175K | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV66413181; called by muse, mutect2, varscan2
- CFHR3 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.988); catalogued as rs756348984, COSV66401900; called by muse, mutect2, varscan2
- CFHR3 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.773); catalogued as COSV66401552; called by muse, mutect2, varscan2
- CGAS | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV100943698; called by muse, mutect2, varscan2
- CHAF1A | c.781C>T p.Q261* | Nonsense Mutation (SNP) | VAF 9/53 reads (17%) | catalogued as COSV100011539; called by muse, mutect2, varscan2
- CHAT | c.2200G>A p.A734T | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV100341041; called by muse, mutect2, varscan2
- CHD5 | c.5723G>A p.G1908E | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.28); PolyPhen benign (0.269); catalogued as COSV99315363; called by muse, mutect2, varscan2
- CHD5 | c.5722G>A p.G1908R | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.1); PolyPhen benign (0.354); catalogued as rs1332890670, COSV52422025; called by muse, mutect2, varscan2
- CHD7 | c.5756C>T p.A1919V | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.235); catalogued as COSV101418521; called by muse, mutect2, varscan2
- CHRDL2 | c.785G>A p.G262E | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99733655; called by muse, mutect2, varscan2
- CHRNB3 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99251551; called by muse, mutect2, varscan2
- CHST11 | c.683C>G p.A228G | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV57994074, COSV99075996; called by muse, mutect2, varscan2
- CHST15 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs199887555, COSV60560141, COSV60560330; called by muse, mutect2, varscan2
- CILP | c.1714C>T p.R572C | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753593002, COSV56026231; called by muse, mutect2, varscan2
- CILP2 | c.2911G>A p.G971R | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99365272; called by muse, mutect2, varscan2
- CKAP5 | c.5921C>T p.S1974F (on ENST00000529230 / NM_001008938.4; = p.S1914F on NM_014756.3) | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs376393422; called by muse, mutect2, varscan2
- CLASP1 | c.4592C>A p.S1531Y | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.974); catalogued as COSV55343716, COSV99757527; called by muse, mutect2, varscan2
- CLCN1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 16/86 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); catalogued as COSV100578549, COSV58372214; called by muse, varscan2
- CLCNKB | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs762535125, COSV100990501; called by muse, mutect2, varscan2
- CLDN25 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 36/128 reads (28%) | catalogued as rs754824119, COSV71620427, COSV71620465; called by muse, mutect2, varscan2
- CLDN9 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 79/235 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.271); catalogued as rs1174267683, COSV100172414, COSV60910487; called by muse, mutect2, varscan2
- CLEC4D | c.295C>T p.L99F | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as rs1308793329, COSV55229295; called by muse, mutect2, varscan2
- CLMN | c.1520C>T p.S507F | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); catalogued as COSV54182462; called by muse, mutect2, varscan2
- CLUAP1 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs750671279, COSV58892414; called by muse, mutect2, varscan2
- CMKLR1 | c.554G>A p.G185E (on ENST00000312143 / NM_001142344.2; = p.G183E on NM_004072.3) | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.033); catalogued as COSV56438142; called by muse, mutect2, varscan2
- CNKSR2 | c.2368G>A p.E790K | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.787); catalogued as COSV99670070; called by muse, mutect2, varscan2
- CNTN3 | c.1267G>A p.V423M | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV55184782, COSV99726304; called by muse, mutect2, varscan2
- CNTNAP5 | c.2533C>T p.P845S | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as COSV101444324, COSV70518197; called by muse, mutect2, varscan2
- COBL | c.3401G>A p.G1134E | Missense Mutation (SNP) | VAF 74/215 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0.054); catalogued as COSV99474463; called by muse, mutect2, varscan2
- COG2 | c.1841C>T p.P614L | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100794811; called by muse, mutect2, varscan2
- COG6 | c.1141C>T p.L381F | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs760641442, COSV100743453; called by muse, mutect2, varscan2
- COG8 | c.959T>C p.L320P | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.916); catalogued as COSV99650952; called by muse, mutect2, varscan2
- COL11A2 | c.2651C>T p.P884L (on ENST00000341947 / NM_080680.3; = p.P777L on NM_080679.2) | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs750723746, COSV100554615; called by muse, mutect2, varscan2
- COL11A2 | c.1267G>A p.G423R (on ENST00000341947 / NM_080680.3; = p.G316R on NM_080679.2) | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100554616; called by muse, mutect2
- COL15A1 | c.2096G>A p.R699K | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.989); catalogued as COSV100898051; called by muse, mutect2, varscan2
- COL15A1 | c.3007G>A p.D1003N | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as rs370574408, COSV104426404; called by muse, mutect2, varscan2
- COL19A1 | c.1964C>T p.P655L | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV100507590; called by muse, mutect2, varscan2
- COL1A2 | c.1037G>A p.G346D | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM072955, COSV51965106; called by muse, mutect2, varscan2
- COL22A1 | c.4511C>T p.P1504L | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.175); catalogued as COSV57365243; called by muse, mutect2, varscan2
- COL22A1 | c.4510C>T p.P1504S | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.572); catalogued as rs775611424, COSV100281127, COSV57364142; called by muse, mutect2, varscan2
- COL22A1 | c.3757C>T p.P1253S | Missense Mutation (SNP) | VAF 40/296 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as COSV100279643, COSV100279857, COSV100281128; called by muse, mutect2, varscan2
- COL3A1 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58587549; called by muse, mutect2, varscan2
- COL4A1 | c.4702C>T p.P1568S | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101011630; called by muse, mutect2, varscan2
- COL4A1 | c.3647G>A p.G1216E | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101011631; called by muse, mutect2, varscan2
- COL4A4 | c.3023G>A p.G1008E | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100307911; called by muse, mutect2, varscan2
- COL5A1 | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs201997623, COSV100880661; called by muse, mutect2, varscan2
- COL6A3 | c.9445G>A p.E3149K | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs138694883; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.2398G>A p.D800N | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.147); catalogued as COSV55088337; called by muse, mutect2, varscan2
- COL8A1 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); catalogued as COSV99658609; called by muse, mutect2, varscan2
- COL9A1 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.91); PolyPhen benign (0.143); catalogued as COSV100294997; called by muse, mutect2, varscan2
- COL9A1 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.715); catalogued as COSV100611883; called by muse, mutect2, varscan2
- COL9A2 | c.596G>A p.G199E | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867691837, COSV101025794; called by muse, mutect2, varscan2
- COLEC12 | c.1630C>T p.P544S | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.562); catalogued as COSV101232204; called by muse, mutect2, varscan2
- COPG1 | c.929C>T p.T310I | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100136017; called by muse, mutect2, varscan2
- CORIN | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99904601; called by muse, mutect2, varscan2
- COX7B2 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV100261234, COSV57217291; called by muse, mutect2, varscan2
- CPED1 | c.1657C>T p.P553S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV59997041; called by muse, mutect2
- CPLANE1 | c.9250C>T p.P3084S | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.067); catalogued as COSV57060042; called by muse, mutect2, varscan2
- CPVL | c.1220G>A p.G407E | Missense Mutation (SNP) | VAF 58/225 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV99606526; called by muse, varscan2
- CPVL | c.1209G>A p.M403I | Missense Mutation (SNP) | VAF 86/238 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as COSV99606529; called by muse, varscan2
- CR2 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV100889720; called by muse, mutect2, varscan2
- CRB1 | c.1950G>A p.W650* | Nonsense Mutation (SNP) | VAF 51/172 reads (30%) | catalogued as COSV100958100, COSV66330615; called by muse, mutect2, varscan2
- CRYGB | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.649); catalogued as COSV53680520; called by muse, mutect2, varscan2
- CRYZ | c.859C>T p.Q287* | Nonsense Mutation (SNP) | VAF 21/94 reads (22%) | catalogued as COSV100558737; called by muse, mutect2, varscan2
- CSAG1 | c.210A>T p.E70D | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT tolerated, low confidence (0.42); PolyPhen probably damaging (0.979); catalogued as COSV100767520; called by muse, mutect2, varscan2
- CSF1R | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.121); catalogued as rs777789969, COSV99643334; called by muse, mutect2, varscan2
- CSF2RA | c.1033C>T p.L345F | Missense Mutation (SNP) | VAF 180/417 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.635); catalogued as COSV100817996; called by muse, mutect2, varscan2
- CSF2RA | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 85/220 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV62625025; called by muse, mutect2, varscan2
- CSH1 | c.10G>A p.G4S | Missense Mutation (SNP) | VAF 118/209 reads (56%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV100298474; called by muse, mutect2, varscan2
- CSH2 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.998); catalogued as COSV100400359; called by muse, mutect2, varscan2
- CSMD1 | c.2902G>A p.G968R (on ENST00000520002; = p.G967R on NM_033225.6) | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100151722; called by muse, mutect2
- CSMD1 | c.1865G>A p.R622Q (on ENST00000520002; = p.R621Q on NM_033225.6) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1197438135, COSV59387484; called by muse, mutect2, varscan2
- CSMD1 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs770518582, COSV68166947; called by muse, mutect2, varscan2
- CSPG4 | c.1822C>T p.Q608* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as COSV100414249; called by muse, varscan2
- CSPG4 | c.1804C>T p.P602S | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.346); catalogued as COSV100414250; called by muse, varscan2
- CST8 | c.241C>T p.L81F | Missense Mutation (SNP) | VAF 90/282 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV55671597, COSV99849945, COSV99850115; called by muse, mutect2, varscan2
- CTPS1 | c.374T>G p.V125G | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101009441; called by muse, mutect2, varscan2
- CUBN | c.6451G>A p.D2151N | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100913681; called by muse, mutect2, varscan2
- CUX1 | c.959C>T p.S320L (on ENST00000292535 / NM_181552.4; = p.S331L on NM_001913.5) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as rs1383544162, COSV99470313; called by muse, mutect2, varscan2
- CUX1 | c.2611C>T p.Q871* | Nonsense Mutation (SNP) | VAF 46/120 reads (38%) | catalogued as COSV99473389; called by muse, mutect2, varscan2
- CWH43 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs755347963, COSV99893684; called by muse, mutect2, varscan2
- CXCL17 | c.98G>A p.R33K | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as COSV100544892; called by muse, mutect2, varscan2
- CXXC1 | c.1715T>A p.V572D | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99497411; called by muse, mutect2, varscan2
- CXXC1 | c.1714G>A p.V572I | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); catalogued as COSV99497416; called by muse, mutect2, varscan2
- CYB5D2 | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100029060; called by muse, mutect2, varscan2
- CYP1A1 | c.538G>A p.G180R | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.05); catalogued as rs775144476, COSV101122386; called by muse, mutect2, varscan2
- CYP2C8 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as CM115008, COSV64878951; called by muse, mutect2, varscan2
- CYP4A11 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); catalogued as COSV100152675; called by muse, mutect2, varscan2
- CYP4F3 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV55410740; called by muse, mutect2, varscan2
- CYP4F8 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57853700; called by muse, mutect2, varscan2
- CYREN | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV99313348; called by muse, mutect2, varscan2
- CYTH4 | c.1132C>T p.P378S | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as COSV99958241; called by muse, mutect2, varscan2
- DAAM1 | c.1688C>T p.P563L | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1368918392, COSV100658723; called by mutect2, varscan2
- DALRD3 | c.100C>T p.H34Y | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.469); catalogued as COSV100482930; called by muse, mutect2, varscan2
- DCAF5 | c.1883C>T p.S628F | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV100432882; called by muse, mutect2, varscan2
- DCAF8L1 | c.1395G>A p.W465* | Nonsense Mutation (SNP) | VAF 7/12 reads (58%) | catalogued as COSV101491569; called by muse, mutect2, varscan2
- DCST1 | c.1543C>T p.R515W | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751470323, COSV99665412; called by muse, mutect2, varscan2
- DCUN1D3 | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 48/127 reads (38%) | catalogued as COSV60953014; called by muse, mutect2, varscan2
- DDR2 | c.1385C>T p.P462L | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as COSV100906922; called by muse, mutect2, varscan2
- DENND4C | c.5188C>T p.P1730S (on ENST00000434457 / NM_001330640.2; = p.P1681S on NM_017925.7) | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs773446530, COSV100727635; called by muse, mutect2, varscan2
- DENND4C | c.5189C>T p.P1730L (on ENST00000434457 / NM_001330640.2; = p.P1681L on NM_017925.7) | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs778640596, COSV100727637; called by muse, mutect2, varscan2
- DENND6B | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV101306118, COSV69807783; called by muse, mutect2, varscan2
- DEUP1 | c.1135C>T p.Q379* | Nonsense Mutation (SNP) | VAF 3/18 reads (17%) | catalogued as COSV99977723; called by muse, mutect2, varscan2
- DGKG | c.1252G>A p.G418S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV99404569; called by muse, mutect2, varscan2
- DGKH | c.1421C>T p.P474L | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV99819708; called by muse, mutect2, varscan2
- DHCR7 | c.1053C>G p.F351L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100832176; called by muse, mutect2, varscan2
- DIS3 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.392); catalogued as COSV66706465; called by muse, mutect2, varscan2
- DMBT1 | c.7558G>A p.E2520K (on ENST00000338354 / NM_001377530.1; = p.E1763K on NM_004406.3) | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as COSV57534694; called by muse, mutect2, varscan2
- DMTN | c.844C>T p.Q282* | Nonsense Mutation (SNP) | VAF 55/181 reads (30%) | catalogued as COSV99742247; called by muse, mutect2, varscan2
- DMXL1 | c.3550C>T p.P1184S | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs772847263, COSV60715571; called by muse, mutect2, varscan2
- DNA2 | c.2639C>T p.P880L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV100622877; called by muse, mutect2, varscan2
- DNAH10 | c.5588A>C p.N1863T (on ENST00000409039; = p.N1802T on NM_207437.3) | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV101292906; called by muse, mutect2, varscan2
- DNAH10 | c.9349G>A p.E3117K (on ENST00000409039; = p.E3056K on NM_207437.3) | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); catalogued as COSV101292908; called by muse, mutect2, varscan2
- DNAH11 | c.3301G>A p.D1101N | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.944); catalogued as rs770039475, COSV100181239; called by muse, mutect2, varscan2
- DNAH11 | c.6728G>A p.R2243Q | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs762176618, COSV60956814; called by muse, mutect2, varscan2
- DNAH3 | c.8698G>A p.V2900M | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs755089569, COSV99771131; called by muse, mutect2, varscan2
- DNAH5 | c.12849T>G p.F4283L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.914); catalogued as COSV99455075; called by muse, mutect2, varscan2
- DNAH5 | c.7946G>A p.G2649E | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV54202287, COSV99451585; called by muse, mutect2, varscan2
- DNAH9 | c.6310C>T p.P2104S | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV99308612; called by muse, mutect2
- DNAH9 | c.8075C>T p.S2692F | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV99305696; called by muse, mutect2, varscan2
- DNAI2 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 47/67 reads (70%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as COSV56757173; called by muse, mutect2, varscan2
- DNAI4 | c.659G>A p.R220K | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV100925248; called by muse, mutect2, varscan2
- DNAJC13 | c.2896C>T p.P966S | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.186); catalogued as COSV99608277; called by muse, mutect2, varscan2
- DNAJC25 | c.376C>T p.H126Y | Missense Mutation (SNP) | VAF 87/151 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV100543475; called by muse, mutect2, varscan2
- DNER | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.559); catalogued as rs772555280, COSV59162827; called by muse, mutect2, varscan2
- DNLZ | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as COSV99396115; called by muse, mutect2, varscan2
- DOC2A | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV100451422; called by muse, mutect2, varscan2
- DOK2 | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99374997; called by muse, mutect2, varscan2
- DOK4 | c.947G>A p.G316E | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs1442353252, COSV99538503; called by muse, mutect2, varscan2
- DOK4 | c.946G>A p.G316R | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs755831982, COSV99538505; called by muse, mutect2, varscan2
- DONSON | c.1427T>G p.I476S | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV99280129; called by muse, mutect2, varscan2
- DOP1A | c.5838-1G>A p.X1946_splice | Splice Site (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99383089; called by muse, mutect2, varscan2
- DPEP2 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as rs144507252, CM142369, COSV99263253; called by muse, mutect2, varscan2
- DPH1 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 46/172 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99559731; called by muse, mutect2, varscan2
- DPPA4 | c.751C>T p.H251Y | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.076); catalogued as rs267599536, COSV100169760; called by muse, mutect2, varscan2
- DQX1 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as COSV66353687; called by muse, mutect2, varscan2
- DSCAM | c.3604G>A p.A1202T | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.096); catalogued as COSV101261697; called by muse, varscan2
- DSCAM | c.3361C>T p.L1121F | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs1379697712, COSV101261698, COSV68024223; called by muse, mutect2, varscan2
- DSG1 | c.2563G>A p.D855N | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs561112685, COSV57133677; called by muse, varscan2
- DSPP | c.896C>T p.S299L | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.895); catalogued as COSV56808990; called by muse, mutect2, varscan2
- DVL3 | c.1202T>A p.L401Q | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.131); catalogued as COSV100493840, COSV57454741; called by muse, mutect2, varscan2
- DYNC1LI1 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.996); catalogued as COSV99818400; called by muse, mutect2, varscan2
- DYRK1B | c.1645C>T p.L549F | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.094); catalogued as COSV59915051; called by muse, mutect2, varscan2
- DYRK3 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 89/225 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as COSV100895856; called by muse, mutect2, varscan2
- ECEL1 | c.1157C>T p.S386L | Missense Mutation (SNP) | VAF 43/191 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1194236279, COSV100459089; called by muse, mutect2, varscan2
- ECHDC1 | c.764G>A p.G255E (on ENST00000531967 / NM_001139510.1; = p.G249E on NM_001002030.2) | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV100541935; called by muse, mutect2, varscan2
- ECHDC1 | c.763G>A p.G255R (on ENST00000531967 / NM_001139510.1; = p.G249R on NM_001002030.2) | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV100541938; called by muse, mutect2, varscan2
- ECT2 | c.1646C>T p.P549L (on ENST00000392692 / NM_001349098.2; = p.P518L on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV99222009; called by muse, mutect2, varscan2
- ECT2 | c.2668C>T p.P890S (on ENST00000392692 / NM_001349098.2; = p.P859S on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.073); catalogued as COSV99222014; called by muse, mutect2, varscan2
- EDAR | c.850G>C p.V284L | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99304406; called by muse, mutect2, varscan2
- EFCAB12 | c.866C>T p.S289F | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.66); catalogued as COSV58175426; called by muse, mutect2, varscan2
- EGR4 | c.895G>A p.D299N (on ENST00000545030; = p.D196N on NM_001965.4) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1436159745, COSV101474276; called by muse, mutect2, varscan2
- EHMT1 | c.2713G>A p.E905K | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71777841; called by muse, mutect2, varscan2
- EIF2AK3 | c.1018G>A p.A340T | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as COSV100304192; called by muse, mutect2, varscan2
- EIF2B1 | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV99967684; called by muse, mutect2, varscan2
- EIF4G3 | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99945889; called by muse, mutect2, varscan2
- ELMOD2 | c.574C>T p.L192F | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100063112; called by muse, mutect2, varscan2
- ENAM | c.2902G>A p.E968K | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.096); catalogued as rs868759180, COSV68535291; called by muse, mutect2, varscan2
- ENPP2 | c.2132G>A p.R711Q (on ENST00000075322 / NM_001040092.3; = p.R763Q on NM_006209.5) | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.251); catalogued as COSV99309521; called by muse, mutect2, varscan2
- ENPP2 | c.1639G>A p.E547K (on ENST00000075322 / NM_001040092.3; = p.E599K on NM_006209.5) | Missense Mutation (SNP) | VAF 80/192 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99309523; called by muse, mutect2, varscan2
- ENPP3 | c.2432G>A p.R811Q | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.499); catalogued as rs373257029, COSV100718197; called by muse, mutect2, varscan2
- EP400 | c.4363C>T p.P1455S | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs746859425, COSV100202492; called by muse, mutect2, varscan2
- EPB41L3 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59460070; called by muse, mutect2, varscan2
- EPHA6 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101065962; called by muse, mutect2, varscan2
- EPHA7 | c.1807C>T p.P603S | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs868510824, COSV65177406, COSV65194672; called by muse, mutect2, varscan2
- EPHX3 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as rs370511610; called by muse, mutect2, varscan2
- ERCC2 | c.2131G>A p.D711N | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs763610846, COSV101228937, COSV67269723; called by muse, mutect2, varscan2
- ERCC6 | c.1676C>T p.S559L | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.166); catalogued as COSV100876298, COSV63392769; called by muse, mutect2, varscan2
- ERN2 | c.134C>T p.T45I | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99892633; called by muse, mutect2, varscan2
- ESPNL | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100547965; called by muse, mutect2, varscan2
- ESPNL | c.2983G>A p.E995K | Missense Mutation (SNP) | VAF 54/165 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV58034510; called by muse, mutect2, varscan2
- ESR2 | c.865T>C p.F289L | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.076); catalogued as CM061726, COSV99963993; called by muse, mutect2, varscan2
- ESR2 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as COSV99963997; called by muse, mutect2, varscan2
- ETAA1 | c.1391C>T p.S464L | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as rs1002675613, COSV99712998; called by muse, mutect2
- ETS2 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 76/295 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs771905336, COSV100711400; called by muse, mutect2, varscan2
- EVPL | c.5200G>A p.E1734K | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV101440980, COSV101440985; called by muse, mutect2, varscan2
- EWSR1 | c.1669C>T p.P557S | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.61); catalogued as COSV100132190; called by muse, mutect2, varscan2
- EXOC2 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.158); catalogued as COSV100034301; called by muse, mutect2, varscan2
- EXTL3 | c.552T>A p.D184E | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99594421; called by muse, mutect2, varscan2
- EYA1 | c.76G>T p.G26C | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.728); catalogued as rs199664417, COSV100380424, COSV58177967; called by muse, varscan2
- EZH1 | c.2161del p.E721Kfs*62 | Frame Shift Del (DEL) | VAF 44/224 reads (20%) | catalogued as COSV52853871; called by mutect2, pindel, varscan2
- F13A1 | c.1241C>T p.S414L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1396702202, CM023371, CM993150, COSV53560635; called by muse, varscan2
- F9 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV99496965; called by muse, mutect2, varscan2
- FAF2 | c.1222C>T p.P408S | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56132932; called by muse, mutect2, varscan2
- FAM120A | c.1171G>A p.G391S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.072); catalogued as COSV99466777; called by mutect2, varscan2
- FAM135B | c.1861G>A p.G621R | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs762317177, COSV52740710; called by muse, mutect2, varscan2
- FAM13A | c.1748C>T p.S583F | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV99984824; called by muse, mutect2
- FAM170A | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.6); catalogued as rs1195724323, COSV58923975, COSV58927567; called by muse, mutect2, varscan2
- FAM193A | c.3431C>T p.S1144F | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100219658; called by muse, mutect2, varscan2
- FAM221B | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs267602231, COSV100941219; called by muse, mutect2, varscan2
- FAM221B | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV65073698; called by muse, mutect2, varscan2
- FAM3D | c.371G>A p.G124E | Missense Mutation (SNP) | VAF 52/214 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1332134866, COSV100717046; called by muse, varscan2
- FAM50B | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.313); catalogued as COSV100976627; called by muse, mutect2, varscan2
- FAM53B | c.166T>G p.C56G | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99785076; called by muse, mutect2, varscan2
- FANCD2 | c.2035C>T p.P679S | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs747164592, COSV55033860; called by muse, varscan2
- FANCF | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 47/187 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.673); catalogued as rs893075597, COSV100541911, COSV59415753; called by muse, mutect2, varscan2
- FAP | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 83/249 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as COSV51865647; called by muse, mutect2, varscan2
- FAR1 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV100701677; called by muse, mutect2, varscan2
- FAT4 | c.4367C>T p.S1456F | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); catalogued as COSV101272018; called by muse, mutect2, varscan2
- FBH1 | c.923C>T p.P308L (on ENST00000362091 / NM_178150.3; = p.P359L on NM_032807.4) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV100758963; called by muse, mutect2, varscan2
- FBN1 | c.8189G>A p.R2730Q | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs200231626; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBN1 | c.4654G>A p.E1552K | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.269); catalogued as COSV57319001; called by muse, mutect2, varscan2
- FBXW10 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1230086494, COSV100111451, COSV100111810; called by muse, mutect2, varscan2
- FCGRT | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs759988303, COSV99675382; called by muse, mutect2, varscan2
- FCRL1 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.92); PolyPhen benign (0.021); catalogued as rs1018021100, COSV100839920; called by muse, mutect2, varscan2
- FCRL5 | c.1417C>T p.P473S | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100708724; called by muse, mutect2, varscan2
- FER | c.2410C>T p.R804C | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777925363, COSV55284265; called by muse, mutect2, varscan2
- FGA | c.1957C>T p.P653S | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.359); catalogued as COSV100120809; called by muse, mutect2, varscan2
- FGFR4 | c.2120G>A p.R707Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761135791, COSV52803677; called by muse, mutect2, varscan2
- FLG | c.8371G>A p.G2791R | Missense Mutation (SNP) | VAF 162/918 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.01); catalogued as rs774083576, COSV100912353; called by muse, mutect2, varscan2
- FLG | c.7558G>A p.D2520N | Missense Mutation (SNP) | VAF 202/596 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs866141505, COSV64236630; called by muse, mutect2, varscan2
- FLI1 | c.368G>A p.R123K | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as COSV99858178; called by muse, mutect2, varscan2
- FLNA | c.3730C>T p.P1244S | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61037345; called by muse, mutect2, varscan2
- FLNB | c.1933C>T p.P645S | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as COSV99915296; called by muse, mutect2, varscan2
- FLNC | c.4015C>T p.P1339S | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100368905; called by muse, mutect2
- FLNC | c.8001G>A p.M2667I | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as COSV99972556; called by muse, mutect2, varscan2
- FMNL3 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99527172; called by muse, mutect2, varscan2
- FMO1 | c.1529C>T p.P510L | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100707712, COSV100707982; called by muse, mutect2, varscan2
- FMR1NB | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV63272717; called by muse, mutect2, varscan2
- FN1 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 120/368 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs769681616, COSV100118488; called by muse, mutect2, varscan2
- FOLH1 | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs267602925, COSV57045271; called by mutect2, varscan2
- FOS | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); catalogued as rs1452209833, COSV100338646; called by muse, varscan2
- FOXE1 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs753424854, COSV100910000, COSV64300603; called by mutect2, varscan2
- FOXO1 | c.1217C>T p.S406L | Missense Mutation (SNP) | VAF 49/184 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1310591117, COSV65426799; called by muse, mutect2, varscan2
- FOXRED2 | c.1310T>G p.V437G | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV99341177; called by muse, mutect2, varscan2
- FRAS1 | c.6094G>A p.D2032N | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99356333; called by muse, mutect2, varscan2
- FRMPD3 | c.3728C>T p.S1243F | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.611); catalogued as COSV99347233; called by muse, mutect2, varscan2
- FRYL | c.5402-1G>A p.X1801_splice | Splice Site (SNP) | VAF 22/67 reads (33%) | catalogued as COSV99978406; called by muse, mutect2, varscan2
- FSD2 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV58009690; called by muse, varscan2
- FSD2 | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100575328; called by muse, varscan2
- FSHR | c.1741G>A p.D581N | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); catalogued as COSV100438254; called by muse, mutect2, varscan2
- FSIP1 | c.1604C>T p.P535L | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.31); catalogued as rs747876924, COSV100618385; called by muse, mutect2, varscan2
- FSIP2 | c.20696C>T p.S6899F | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100555561, COSV100556762; called by muse, mutect2, varscan2
- FUT1 | c.800G>A p.W267* | Nonsense Mutation (SNP) | VAF 44/168 reads (26%) | catalogued as rs548079884, COSV100038296; called by muse, mutect2, varscan2
- FYB1 | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100686547; called by muse, mutect2, varscan2
- FYCO1 | c.2747C>T p.T916I | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV99946362; called by muse, mutect2, varscan2
- FYN | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99992664; called by muse, mutect2, varscan2
- G3BP1 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs896356394, COSV62365718; called by muse, mutect2, varscan2
- GABRA2 | c.188-1G>A p.X63_splice | Splice Site (SNP) | VAF 19/72 reads (26%) | catalogued as COSV100734821; called by muse, mutect2
- GALNT10 | c.951G>A p.M317I | Missense Mutation (SNP) | VAF 57/228 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99770047; called by muse, mutect2, varscan2
- GALNTL6 | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV101560651; called by muse, mutect2, varscan2
- GAS2L3 | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV57158584; called by muse, mutect2, varscan2
- GBP1 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 53/189 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as COSV100976315; called by muse, mutect2, varscan2
- GCC2 | c.4460C>T p.S1487F | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100565676; called by mutect2, varscan2
- GCH1 | c.746G>A p.R249K | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1468205954, COSV99582152; called by muse, mutect2, varscan2
- GCHFR | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as COSV99549209; called by muse, mutect2, varscan2
- GCN1 | c.2246C>T p.S749F | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV100326172, COSV56110687; called by muse, varscan2
- GCN1 | c.2192C>T p.S731F | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as COSV100325312; called by muse, varscan2
- GDF6 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99748657; called by muse, mutect2, varscan2
- GEMIN2 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.268); catalogued as rs763604052, COSV99158519; called by muse, mutect2, varscan2
- GEMIN2 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV99158526; called by muse, mutect2, varscan2
- GEMIN5 | c.2345G>A p.G782E | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.013); catalogued as COSV99594398; called by muse, mutect2, varscan2
- GFOD2 | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 55/102 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV99263764; called by muse, mutect2, varscan2
- GFPT1 | c.1790C>T p.P597L (on ENST00000357308 / NM_001244710.2; = p.P579L on NM_002056.4) | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100623021; called by muse, mutect2, varscan2
- GFPT2 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs374554363; called by muse, mutect2, varscan2
- GHR | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV50117051; called by muse, mutect2, varscan2
- GHRL | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 78/312 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.689); catalogued as rs756969269, COSV99814068; called by muse, mutect2, varscan2
- GIGYF2 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1228793071, COSV65250825; called by muse, mutect2, varscan2
- GIGYF2 | c.1010C>T p.S337F | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV101004647; called by muse, mutect2, varscan2
- GJD2 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99290940; called by muse, mutect2, varscan2
- GJD2 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51750184; called by muse, mutect2, varscan2
- GK2 | c.1457G>A p.R486Q | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs774708528, COSV62626317; called by muse, mutect2, varscan2
- GK2 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1321996211, COSV62626188; called by muse, mutect2, varscan2
- GLDC | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100394681; called by muse, mutect2, varscan2
- GLO1 | c.409A>T p.S137C | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV100974117; called by muse, mutect2, varscan2
- GLP2R | c.1456G>A p.G486S | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV52323268; called by muse, mutect2, varscan2
- GLTP | c.544C>T p.L182F | Missense Mutation (SNP) | VAF 113/364 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.152); catalogued as COSV100570417; called by muse, mutect2, varscan2
- GMFG | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV53419111; called by muse, mutect2, varscan2
- GOLGA3 | c.160del p.E54Kfs*51 | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | catalogued as COSV52644771; called by mutect2, pindel, varscan2
- GOLGA4 | c.1418C>T p.S473F | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV100729212; called by muse, mutect2, varscan2
- GPATCH2 | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV100861433; called by muse, mutect2, varscan2
- GPC5 | c.460G>A p.G154S | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs758061320, COSV100996256; called by muse, mutect2, varscan2
- GPR119 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs1348551327, COSV52275219; called by muse, varscan2
- GPR119 | c.898G>A p.V300M | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.125); catalogued as COSV99358739; called by muse, varscan2
- GPR4 | c.689T>A p.I230N | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV100547226; called by muse, mutect2, varscan2
- GRB7 | c.283C>A p.P95T | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100485667; called by muse, mutect2, varscan2
- GRB7 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV100485669; called by muse, mutect2, varscan2
- GRHL2 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as COSV52557299; called by muse, mutect2, varscan2
- GRID1 | c.2231C>T p.A744V | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV60048574; called by muse, varscan2
- GRIK4 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 55/282 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.403); catalogued as COSV101483847; called by muse, mutect2, varscan2
- GRIN2A | c.3593C>T p.S1198F | Missense Mutation (SNP) | VAF 199/497 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.602); catalogued as COSV58044622; called by muse, mutect2, varscan2
- GRIN2A | c.2692C>T p.L898F | Missense Mutation (SNP) | VAF 64/206 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV100411280, COSV58060819; called by muse, mutect2, varscan2
- GRIN2B | c.3343C>T p.R1115C | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.862); catalogued as rs370908319; called by muse, varscan2
- GRIN2B | c.3296G>A p.R1099H | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.98); catalogued as COSV101663212; called by muse, varscan2
- GRM5 | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs774109600, COSV100554874; called by muse, mutect2, varscan2
- GRM8 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100286573; called by muse, mutect2, varscan2
- GRXCR1 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV101295763; called by muse, mutect2
- GTF2IRD2B | c.2396C>A p.T799K | Missense Mutation (SNP) | VAF 58/199 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100441307; called by muse, mutect2, varscan2
- GTF3C1 | c.4586G>A p.R1529K | Missense Mutation (SNP) | VAF 99/235 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62239856; called by muse, mutect2, varscan2
- GTF3C2 | c.2650C>T p.H884Y | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.091); catalogued as COSV99273354; called by muse, mutect2, varscan2
- GUCY2D | c.2248G>A p.E750K | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.491); catalogued as CM057705, COSV99644354; called by muse, mutect2, varscan2
- H3-5 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.847); catalogued as rs866971809, COSV61186810; called by muse, mutect2, varscan2
- HACL1 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100337418; called by muse, mutect2, varscan2
- HADHB | c.633C>T p.L211= | Splice Region (SNP) | VAF 40/119 reads (34%) | catalogued as COSV100502199; called by muse, mutect2, varscan2
- HAL | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 39/276 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.046); catalogued as COSV99701697; called by muse, mutect2, varscan2
- HAVCR1 | c.140G>A p.W47* | Nonsense Mutation (SNP) | VAF 12/49 reads (24%) | catalogued as COSV100208660; called by muse, mutect2, varscan2
- HAVCR1 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.048); catalogued as COSV100208662; called by muse, mutect2, varscan2
- HCFC2 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99983339; called by muse, mutect2, varscan2
- HCK | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV52940118; called by muse, mutect2, varscan2
- HCN1 | c.1946C>T p.S649F | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs759733460, COSV100302693, COSV57525389; called by muse, mutect2, varscan2
- HDAC4 | c.1049C>T p.S350F | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as COSV100614415; called by muse, mutect2, varscan2
- HDAC5 | c.774C>T p.A258= | Splice Region (SNP) | VAF 48/75 reads (64%) | catalogued as COSV99871151; called by muse, mutect2, varscan2
- HDAC9 | c.1916C>T p.P639L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV67769768; called by muse, mutect2
- HELT | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV58819612; called by muse, mutect2, varscan2
- HEPACAM | c.137C>T p.T46I | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.985); catalogued as COSV100005966; called by muse, mutect2, varscan2
- HEPACAM | c.44T>A p.L15Q | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.083); catalogued as COSV100005969; called by muse, mutect2, varscan2
- HERC2 | c.12570G>A p.K4190= | Splice Region (SNP) | VAF 8/24 reads (33%) | catalogued as COSV99877351; called by muse, mutect2, varscan2
- HGF | c.1993G>A p.G665R | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as COSV99738789; called by muse, mutect2, varscan2
- HGF | c.465G>A p.M155I | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.403); catalogued as COSV99738793; called by muse, mutect2, varscan2
- HIF3A | c.88G>A p.E30K (on ENST00000377670 / NM_152795.4; = p.R9= on NM_022462.4) | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1399400602, COSV99356113; called by muse, mutect2
- HIF3A | c.1880G>A p.S627N (on ENST00000377670 / NM_152795.4; = p.S558N on NM_022462.4) | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.012); catalogued as COSV99355912; called by muse, mutect2, varscan2
- HIVEP2 | c.6805G>A p.E2269K | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as COSV99175990; called by muse, mutect2, varscan2
- HIVEP3 | c.5208-1G>A p.X1736_splice | Splice Site (SNP) | VAF 14/39 reads (36%) | catalogued as COSV99914223; called by muse, mutect2, varscan2
- HMCN1 | c.2477G>A p.W826* | Nonsense Mutation (SNP) | VAF 35/112 reads (31%) | catalogued as COSV99637041; called by muse, mutect2, varscan2
- HMCN1 | c.10018C>T p.P3340S | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99637042; called by muse, mutect2, varscan2
- HMCN1 | c.10537G>A p.G3513R | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV54949594; called by muse, mutect2, varscan2
- HMG20A | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100287985; called by muse, mutect2, varscan2
- HNF4A | c.1156C>T p.H386Y | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV100291673, COSV100291797; called by muse, mutect2, varscan2
- HNMT | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV54506572, COSV54506703; called by muse, mutect2, varscan2
- HNRNPR | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100164733; called by muse, mutect2, varscan2
- HOXA3 | c.1231G>A p.G411R | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs772165466, COSV100415739; called by muse, mutect2, varscan2
- HPDL | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.64); PolyPhen benign (0.054); catalogued as COSV100588224; called by muse, mutect2, varscan2
- HRC | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV99418427; called by muse, mutect2, varscan2
- HRG | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV99215143; called by muse, mutect2, varscan2
- HRH1 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.97); PolyPhen benign (0.007); catalogued as COSV101229121; called by muse, mutect2, varscan2
- HS6ST3 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100941831; called by muse, mutect2, varscan2
- HSP90AB1 | c.2119G>A p.E707K | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as COSV99241472; called by muse, mutect2, varscan2
- HSPA12A | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100980005; called by muse, mutect2, varscan2
- HSPG2 | c.5084C>T p.S1695F | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV65979176; called by muse, mutect2, varscan2
- HTR1F | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.245); catalogued as COSV60391174; called by muse, mutect2, varscan2
- HTR3B | c.959C>T p.S320F | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1366929014, COSV99492373; called by muse, mutect2, varscan2
- HYAL1 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99807938; called by muse, mutect2, varscan2
- HYDIN | c.11491G>A p.G3831R | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101125252; called by muse, mutect2, varscan2
- HYDIN | c.2189G>A p.G730E | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV55485012; called by muse, mutect2, varscan2
- IARS1 | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100986899; called by muse, mutect2, varscan2
- IDO2 | c.925G>A p.E309K (on ENST00000389060; = p.E322K on NM_194294.2) | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as rs1172478780, COSV58425203; called by muse, varscan2
- IFNA17 | c.127C>A p.Q43K | Missense Mutation (SNP) | VAF 59/208 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs370226192; called by muse, mutect2, varscan2
- IFT122 | c.2860G>A p.G954S (on ENST00000348417 / NM_052989.3; = p.G895S on NM_018262.4) | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs1246744473, COSV99959969; called by muse, mutect2, varscan2
- IFT52 | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 129/419 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.082); catalogued as COSV100887689; called by muse, mutect2, varscan2
- IGHV5-51 | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs782384850; called by muse, mutect2, varscan2
- IGKV1-6 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 87/253 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.331); catalogued as rs761608853; called by muse, mutect2, varscan2
- IGKV1D-12 | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as rs759425942; called by mutect2, varscan2
- IGKV1D-17 | c.113G>A p.G38E | Missense Mutation (SNP) | VAF 40/320 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1440886255; called by muse, mutect2
- IGSF9 | c.1934C>T p.P645L (on ENST00000368094 / NM_001135050.2; = p.P629L on NM_020789.4) | Missense Mutation (SNP) | VAF 61/223 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.5); catalogued as COSV63642442; called by muse, mutect2, varscan2
- IGSF9 | c.1315C>T p.P439S (on ENST00000368094 / NM_001135050.2; = p.P423S on NM_020789.4) | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63643444; called by muse, mutect2, varscan2
- IGSF9B | c.1373G>A p.G458E | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100318569; called by muse, mutect2, varscan2
- IKZF1 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.115); catalogued as COSV58783378, COSV58790054; called by muse, mutect2
- IL1RAPL2 | c.1715C>T p.S572F | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as COSV100782144, COSV100782148; called by muse, mutect2, varscan2
- ILDR1 | c.1087G>A p.D363N (on ENST00000344209 / NM_001199799.2; = p.D319N on NM_175924.4) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs751310993, COSV99879035; called by muse, mutect2, varscan2
- IMPG1 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.09); catalogued as COSV100886747; called by muse, mutect2
- INCENP | c.2488G>A p.D830N (on ENST00000394818 / NM_001040694.2; = p.D826N on NM_020238.3) | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs913193046, COSV99610797; called by muse, mutect2, varscan2
- INKA2 | c.685A>T p.K229* | Nonsense Mutation (SNP) | VAF 40/93 reads (43%) | catalogued as COSV100615911; called by muse, mutect2, varscan2
- INPP5B | c.907C>T p.R303C (on ENST00000373023; = p.R223C on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/196 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs752264648, COSV65960958; called by muse, mutect2, varscan2
- INPP5D | c.1714C>T p.P572S (on ENST00000445964 / NM_001017915.3; = p.P571S on NM_005541.5) | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.371); catalogued as COSV100856976; called by muse, mutect2, varscan2
- INSYN2A | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.11); catalogued as COSV99733303; called by muse, mutect2, varscan2
- INTS3 | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 62/189 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100016587; called by muse, mutect2, varscan2
- INTS3 | c.1663C>T p.P555S | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as COSV100016589; called by muse, mutect2, varscan2
- INTS5 | c.952C>T p.H318Y | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV100399867; called by muse, mutect2, varscan2
- IQCE | c.125C>T p.S42L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs199648730; called by muse, mutect2, varscan2
- IQCG | c.798T>A p.N266K | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.07); catalogued as COSV99502802; called by muse, mutect2, varscan2
- IQCN | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as COSV101149104; called by muse, mutect2, varscan2
- IQSEC3 | c.532G>A p.G178S | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.86); catalogued as COSV58285073; called by muse, mutect2, varscan2
- IRF2 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV66929239; called by muse, mutect2, varscan2
- ITGA2 | c.2305C>T p.P769S | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56868228; called by muse, mutect2, varscan2
- ITGA9 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.459); catalogued as rs757214035, COSV53241737; called by muse, mutect2, varscan2
- ITGAD | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV101210609; called by muse, mutect2, varscan2
- ITGAE | c.232C>T p.L78F | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV99561657; called by muse, mutect2, varscan2
- ITIH2 | c.2650G>A p.E884K | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV100623467; called by muse, mutect2, varscan2
- ITPK1 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.084); catalogued as COSV99969090; called by muse, mutect2, varscan2
- ITPRID1 | c.573G>A p.M191I | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as rs1402447694, COSV60070890; called by muse, mutect2, varscan2
- JAK3 | c.2768C>A p.A923D | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as COSV101513036; called by muse, mutect2
- JCAD | c.3842C>T p.S1281F | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV100948621; called by muse, mutect2, varscan2
- KALRN | c.1118C>T p.S373F | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1161094085, COSV53761946; called by muse, mutect2, varscan2
- KANSL1 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 58/148 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV99295029; called by muse, mutect2, varscan2
- KANSL1 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 77/261 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as COSV99295031; called by muse, mutect2, varscan2
- KAT6B | c.3155G>A p.R1052Q | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.15); catalogued as rs368055515, COSV99769234; called by muse, mutect2, varscan2
- KCNA1 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs1565433107, COSV66838153; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNAB1 | c.1081G>A p.A361T (on ENST00000490337 / NM_172160.3; = p.A350T on NM_003471.3) | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs1483001307, COSV100205233; called by muse, mutect2, varscan2
- KCNC4 | c.682G>A p.V228M | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV100873705; called by muse, mutect2, varscan2
- KCNE1 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); catalogued as rs1158360034, COSV100492735; called by mutect2, varscan2
- KCNE3 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV59551760; called by muse, mutect2, varscan2
- KCNJ16 | c.163G>A p.G55R | Missense Mutation (SNP) | VAF 75/199 reads (38%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.541); catalogued as COSV99388807; called by muse, mutect2, varscan2
- KCNJ16 | c.595C>T p.L199F | Missense Mutation (SNP) | VAF 59/86 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99388808; called by muse, mutect2, varscan2
- KCNJ2 | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 82/148 reads (55%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV54662329; called by muse, mutect2, varscan2
- KCNK5 | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV100851953; called by muse, mutect2, varscan2
- KDM2A | c.3049C>T p.P1017S | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100445867; called by muse, mutect2, varscan2
- KDM2B | c.1481C>T p.P494L | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782337879, COSV100997691; called by muse, mutect2, varscan2
- KDM3A | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV100461079; called by muse, mutect2, varscan2
- KEL | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); catalogued as COSV62333283, COSV62335023; called by muse, mutect2, varscan2
- KIAA0232 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as COSV100301148; called by muse, mutect2, varscan2
- KIAA0232 | c.2369C>T p.S790F | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs1164504156, COSV100301149; called by muse, mutect2, varscan2
- KIAA0586 | c.3575C>T p.P1192L (on ENST00000619416 / NM_001244190.2; = p.P1131L on NM_014749.5) | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV99709096; called by muse, mutect2, varscan2
- KIAA1328 | c.1633C>T p.R545* | Nonsense Mutation (SNP) | VAF 13/24 reads (54%) | catalogued as rs992833068, COSV54446681; called by muse, mutect2, varscan2
- KIAA1755 | c.2134C>T p.P712S | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54079059; called by muse, mutect2, varscan2
- KIAA1755 | c.1343G>A p.G448E | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.115); catalogued as COSV99642795; called by muse, mutect2, varscan2
- KIF1A | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs879253976, COSV100240178, COSV100242574; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF21A | c.3808C>A p.L1270I (on ENST00000361418 / NM_001378440.1; = p.L1257I on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV100735740; called by muse, mutect2, varscan2
- KIF21A | c.968A>G p.Y323C | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100735743; called by muse, mutect2, varscan2
- KIF26B | c.4735G>A p.G1579R | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100833577; called by muse, mutect2
- KIF9 | c.591+2T>A p.X197_splice | Splice Site (SNP) | VAF 6/15 reads (40%) | catalogued as COSV99647084; called by muse, mutect2
- KIFAP3 | c.2266C>T p.P756S | Missense Mutation (SNP) | VAF 83/280 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100847173, COSV63033435; called by muse, mutect2, varscan2
- KIT | c.2186C>T p.S729F | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV55427028, COSV99855530; called by muse, mutect2, varscan2
- KLB | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV99962535; called by muse, mutect2, varscan2
- KLHL1 | c.2111C>T p.A704V | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.498); catalogued as COSV100918275; called by muse, mutect2, varscan2
- KLHL1 | c.1835C>T p.S612F | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100916855; called by muse, mutect2, varscan2
- KLHL10 | c.1468G>A p.G490R | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV99509409; called by muse, mutect2, varscan2
- KLHL15 | c.65G>A p.R22K | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as COSV100044474; called by muse, mutect2, varscan2
- KLK3 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV100386026; called by muse, varscan2
- KLK3 | c.716G>A p.R239K | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100386141; called by muse, varscan2
- KLRG2 | c.1124G>A p.G375D | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV100572612; called by muse, mutect2, varscan2
- KMT2A | c.7774C>T p.P2592S | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.265); catalogued as COSV100630123; called by muse, mutect2, varscan2
- KMT2D | c.8681C>T p.P2894L | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as rs771221036, COSV56431356; called by muse, mutect2, varscan2
- KMT2D | c.4669C>T p.Q1557* | Nonsense Mutation (SNP) | VAF 6/12 reads (50%) | catalogued as rs1282795733, COSV56412743; called by muse, mutect2, varscan2
- KMT2D | c.2323G>T p.E775* | Nonsense Mutation (SNP) | VAF 14/58 reads (24%) | catalogued as COSV99986373; called by muse, mutect2, varscan2
- KNOP1 | c.539T>C p.V180A | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99575403; called by muse, mutect2, varscan2
- KPNA1 | c.1190G>A p.R397K | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.152); catalogued as COSV100724433; called by muse, mutect2, varscan2
- KRBA2 | c.1255G>A p.G419R | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.449); catalogued as COSV100497733; called by muse, mutect2, varscan2
- KRT23 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 72/130 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs745920229, COSV52927172; called by muse, mutect2, varscan2
- KRT6C | c.49G>A p.G17S | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV99360225; called by muse, mutect2, varscan2
- KRT71 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.166); catalogued as rs778601047, COSV57288926; called by muse, mutect2, varscan2
- KRTAP13-1 | c.254C>T p.T85I | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.335); catalogued as rs1487673357, COSV100819956; called by muse, mutect2, varscan2
- KRTAP19-5 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 48/174 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.118); catalogued as rs770493303, COSV61858950; called by muse, mutect2, varscan2
- KRTAP24-1 | c.239C>T p.T80I | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.12); catalogued as COSV61090106, COSV61090142; called by muse, mutect2, varscan2
- KSR1 | c.2575C>T p.P859S (on ENST00000644974 / NM_001367810.1; = p.P744S on NM_014238.2) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99261035; called by muse, mutect2, varscan2
- L1CAM | c.2174G>A p.G725E | Missense Mutation (SNP) | VAF 142/234 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100649507; called by muse, mutect2, varscan2
- L1CAM | c.1684G>A p.E562K | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.245); catalogued as COSV100649509; called by muse, mutect2, varscan2
- L3MBTL3 | c.1169T>C p.V390A | Missense Mutation (SNP) | VAF 94/255 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100696452; called by muse, mutect2, varscan2
- LAMA4 | c.4960G>A p.E1654K (on ENST00000230538 / NM_001105206.3; = p.E1647K on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/228 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV100037749, COSV100039658; called by muse, mutect2, varscan2
- LAMA4 | c.2891G>A p.G964E (on ENST00000230538 / NM_001105206.3; = p.G957E on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57903271; called by muse, mutect2, varscan2
- LAMC1 | c.2303C>T p.S768F | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs1382833530, COSV99280616; called by muse, mutect2, varscan2
- LAMC3 | c.2380T>C p.F794L | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.63); catalogued as COSV100736126; called by muse, mutect2, varscan2
- LARS1 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99198938; called by muse, mutect2, varscan2
- LAT | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV100209040, COSV57956765; called by muse, mutect2, varscan2
- LATS2 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV66876540; called by muse, mutect2, varscan2
- LCE1C | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 47/89 reads (53%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.003); catalogued as COSV100908494; called by muse, mutect2, varscan2
- LCE2D | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.227); catalogued as COSV64228820, COSV64228862; called by muse, mutect2, varscan2
- LCOR | c.4340C>T p.P1447L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV99617250; called by muse, mutect2, varscan2
- LCT | c.4853G>A p.R1618K | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV99928801, COSV99930625; called by muse, mutect2, varscan2
- LDLRAD1 | c.370C>T p.L124F | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100997638; called by muse, mutect2, varscan2
- LEXM | c.552G>A p.W184* | Nonsense Mutation (SNP) | VAF 23/78 reads (29%) | catalogued as rs747220751, COSV100827792; called by muse, mutect2, varscan2
- LIF | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.746); catalogued as COSV99970006; called by muse, mutect2, varscan2
- LILRA2 | c.1022C>T p.T341I | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); catalogued as COSV99254041; called by muse, mutect2, varscan2
- LILRA4 | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV99393447; called by muse, mutect2, varscan2
- LILRA5 | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV100007143; called by muse, mutect2, varscan2
- LILRB4 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV99554169; called by muse, mutect2, varscan2
- LILRB4 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as COSV99554171; called by muse, mutect2, varscan2
- LIMA1 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV100372752; called by muse, mutect2, varscan2
- LIPG | c.587G>T p.G196V | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99724809; called by muse, mutect2, varscan2
- LMLN | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 54/165 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.05); catalogued as rs758130698, COSV54561092; called by muse, mutect2, varscan2
- LMOD3 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV70456110; called by muse, mutect2, varscan2
- LONRF3 | c.2228G>A p.R743K (on ENST00000371628 / NM_001031855.3; = p.R702K on NM_024778.5) | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100504731; called by muse, mutect2, varscan2
- LPA | c.5893A>T p.N1965Y | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100308247; called by muse, mutect2, varscan2
- LPA | c.1202C>T p.S401L | Missense Mutation (SNP) | VAF 83/1357 reads (6%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.483); catalogued as rs1315920836; called by muse, mutect2
- LPAR3 | c.1024A>T p.I342F | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as COSV101004888; called by muse, mutect2, varscan2
- LRCH2 | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.074); catalogued as COSV100407706; called by muse, mutect2, varscan2
- LRCH2 | c.1579C>T p.P527S | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100407707; called by muse, mutect2, varscan2
- LRFN2 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.186); catalogued as COSV100600011, COSV57831068; called by muse, mutect2, varscan2
- LRIF1 | c.1796C>T p.S599F | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.181); catalogued as COSV100870942; called by muse, mutect2, varscan2
- LRIG3 | c.1424C>T p.P475L | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100292885; called by muse, mutect2, varscan2
- LRIT1 | c.1247G>A p.G416E | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV100928174; called by muse, mutect2, varscan2
- LRIT1 | c.1246G>A p.G416R | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.249); catalogued as COSV100928175; called by muse, mutect2, varscan2
- LRIT1 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as rs369344472; called by muse, mutect2, varscan2
- LRP12 | c.952T>A p.Y318N | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99408453; called by muse, mutect2, varscan2
- LRP12 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1444005150, COSV52629599; called by muse, mutect2, varscan2
- LRP1B | c.11834G>A p.G3945E | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.97); PolyPhen probably damaging (0.999); catalogued as COSV67196683, COSV67230129; called by muse, mutect2, varscan2
- LRP1B | c.10018G>A p.D3340N | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV101261911, COSV67207389; called by muse, mutect2, varscan2
- LRP1B | c.747G>A p.W249* | Nonsense Mutation (SNP) | VAF 8/35 reads (23%) | catalogued as rs769159580, COSV101261913; called by muse, mutect2, varscan2
- LRP3 | c.929T>G p.V310G | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99472617; called by muse, mutect2
- LRRC32 | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99476826; called by muse, mutect2, varscan2
- LRRC4C | c.1282G>A p.V428M | Missense Mutation (SNP) | VAF 57/162 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99538862, COSV99540036; called by muse, mutect2, varscan2
- LRRC7 | c.697G>A p.E233K (on ENST00000651989 / NM_001370785.2; = p.E200K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV50651939; called by muse, mutect2, varscan2
- LRRC7 | c.1981G>A p.E661K (on ENST00000651989 / NM_001370785.2; = p.E628K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as rs200158661, COSV50435197; called by muse, mutect2, varscan2
- LRRC7 | c.3467C>T p.S1156F (on ENST00000651989 / NM_001370785.2; = p.S1123F on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 80/221 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99230321; called by muse, mutect2, varscan2
- LRRK1 | c.3324G>A p.W1108* | Nonsense Mutation (SNP) | VAF 21/84 reads (25%) | catalogued as COSV99443637; called by muse, mutect2, varscan2
- LRRK2 | c.2032C>T p.Q678* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as COSV100111326; called by muse, mutect2, varscan2
- LRRN3 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as COSV100074084; called by muse, mutect2, varscan2
- LRRTM1 | c.1526C>T p.S509L | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs145162573, COSV54442589; called by muse, mutect2, varscan2
- MAB21L2 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV58262662; called by muse, mutect2, varscan2
- MAD1L1 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV99642868; called by muse, mutect2, varscan2
- MAG | c.1018G>A p.G340R | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1436220637, COSV100728101; called by muse, mutect2, varscan2
- MAGEA11 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 48/75 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100290751; called by muse, varscan2
- MAGEB16 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.037); catalogued as COSV101303345; called by muse, mutect2, varscan2
- MAGEC1 | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 49/86 reads (57%) | SIFT tolerated, low confidence (0.38); PolyPhen possibly damaging (0.448); catalogued as rs764103583, COSV53568059; called by muse, mutect2, varscan2
- MAGEC1 | c.2570C>T p.S857F | Missense Mutation (SNP) | VAF 81/131 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV99596743; called by muse, mutect2, varscan2
- MAGI1 | c.4217C>T p.S1406F | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.653); catalogued as rs1430251228, COSV100443347, COSV58319101; called by muse, mutect2, varscan2
- MAGI2 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.197); catalogued as rs765838680, COSV100836853; called by muse, mutect2, varscan2
- MAGI3 | c.412C>T p.L138F | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100290619; called by muse, mutect2, varscan2
- MAP1A | c.3428G>A p.R1143Q | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs751755609, COSV55807650; called by muse, mutect2, varscan2
- MAP1S | c.3178T>C p.*1060Qext*16 | Nonstop Mutation (SNP) | VAF 16/56 reads (29%) | catalogued as rs1274058160, COSV100141290; called by muse, mutect2, varscan2
- MAP3K20 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100169591; called by muse, mutect2, varscan2
- MAP3K5 | c.3215C>T p.S1072F | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.121); catalogued as COSV62886925; called by muse, mutect2, varscan2
- MAP3K9 | c.2635C>T p.P879S (on ENST00000554752 / NM_001284230.1; = p.P893S on NM_033141.4) | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as COSV101173792; called by muse, mutect2, varscan2
- MAP4K2 | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV99581891; called by muse, mutect2, varscan2
- MAPK10 | c.955C>T p.P319S (on ENST00000359221 / NM_001351625.2; = p.P357S on NM_002753.5) | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.233); catalogued as COSV100175587; called by muse, mutect2, varscan2
- MARCHF10 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as rs202126080; called by muse, mutect2, varscan2
- MAST2 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs763839590, COSV63621483; called by muse, mutect2, varscan2
- MAST4 | c.5215C>T p.R1739* (on ENST00000403625 / NM_001164664.2; = p.R1550* on NM_015183.3) | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as COSV99842871; called by muse, mutect2, varscan2
- MATK | c.676G>A p.A226T (on ENST00000310132 / NM_139355.3; = p.A227T on NM_002378.4) | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.099); catalogued as COSV100036341; called by muse, mutect2, varscan2
- MCEE | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as rs1307619613, COSV99731343; called by muse, mutect2
- MCM4 | c.2413T>A p.L805M | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.446); catalogued as COSV100031935; called by muse, mutect2, varscan2
- MCRS1 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV100657454; called by muse, mutect2, varscan2
- MDC1 | c.1715C>T p.P572L | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs749854538, COSV100903126; called by muse, mutect2, varscan2
- ME1 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.103); catalogued as COSV100866717; called by muse, mutect2, varscan2
- MECOM | c.1186G>A p.D396N (on ENST00000468789 / NM_001105078.4; = p.D584N on NM_004991.4) | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV99245249; called by muse, mutect2, varscan2
- MED23 | c.3652C>T p.H1218Y | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100645442; called by muse, mutect2, varscan2
- MED8 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV99318548; called by muse, mutect2, varscan2
- MEGF8 | c.2696C>T p.P899L (on ENST00000251268 / NM_001271938.2; = p.P832L on NM_001410.3) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.095); catalogued as COSV99239496; called by muse, mutect2
- MEIS2 | c.1225C>T p.P409S | Missense Mutation (SNP) | VAF 61/256 reads (24%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV54943513; called by muse, mutect2, varscan2
- MEPE | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100735004; called by muse, mutect2, varscan2
- MFAP5 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as rs145592970; called by muse, mutect2, varscan2
- MFSD6L | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.899); catalogued as COSV100266987; called by muse, mutect2, varscan2
- MFSD8 | c.166G>A p.V56M | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56553136; called by muse, mutect2, varscan2
- MGRN1 | c.1529G>A p.G510E | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV99274985; called by muse, mutect2, varscan2
- MICALL1 | c.1642C>T p.P548S | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV99317614; called by muse, mutect2, varscan2
- MICALL1 | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV99317616; called by muse, mutect2, varscan2
- MICU1 | c.1400C>T p.T467I (on ENST00000361114 / NM_001195518.2; = p.T473I on NM_006077.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV100741963; called by muse, mutect2, varscan2
- MILR1 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV101660247; called by muse, mutect2, varscan2
- MISP | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.977); catalogued as rs138933312; called by muse, mutect2, varscan2
- MISP | c.1262C>T p.P421L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as COSV99297183; called by muse, mutect2, varscan2
- MKI67 | c.5525C>T p.P1842L | Missense Mutation (SNP) | VAF 84/256 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100897058; called by muse, mutect2
- MLH1 | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as COSV99212830; called by muse, mutect2, varscan2
- MLH1 | c.1295T>C p.L432P | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99212831; called by muse, mutect2, varscan2
- MME | c.2026C>T p.P676S | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100852567; called by muse, mutect2, varscan2
- MMP14 | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100314342; called by muse, mutect2, varscan2
- MNT | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99438257; called by muse, mutect2, varscan2
- MORN5 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.461); catalogued as rs1440823538, COSV101056013; called by muse, mutect2
- MOV10 | c.1903C>T p.P635S | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as rs1016367515, COSV53517063; called by muse, mutect2, varscan2
- MPP4 | c.817G>A p.G273R | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV100207439; called by muse, mutect2, varscan2
- MRGPRX1 | c.723G>A p.W241* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as COSV100246176; called by muse, mutect2, varscan2
- MRM1 | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1410869599; called by muse, mutect2, varscan2
- MRTFA | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV100844429; called by muse, mutect2, varscan2
- MS4A1 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT tolerated (0.76); PolyPhen benign (0.027); catalogued as COSV61943281; called by muse, mutect2, varscan2
- MS4A4A | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.509); catalogued as rs140018712, COSV59701315; called by muse, mutect2, varscan2
- MSH4 | c.626T>C p.I209T | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99592705; called by muse, mutect2, varscan2
- MSLNL | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 12/29 reads (41%) | catalogued as COSV99558876; called by muse, mutect2, varscan2
- MST1R | c.2969C>T p.P990L | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV99619888; called by muse, mutect2, varscan2
- MST1R | c.2584C>T p.P862S | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.598); catalogued as COSV56566240; called by muse, mutect2, varscan2
- MTMR12 | c.1721C>T p.P574L | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.516); catalogued as COSV99374174; called by muse, mutect2, varscan2
- MTURN | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as rs748199142, COSV100188923; called by muse, mutect2, varscan2
- MUC16 | c.40846G>A p.G13616R | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated, low confidence (0.26); PolyPhen probably damaging (0.998); catalogued as COSV101110116; called by muse, mutect2
- MUC16 | c.37172C>T p.T12391I | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.439); catalogued as rs1438018459, COSV101202005; called by muse, mutect2, varscan2
- MUC16 | c.26804C>T p.S8935L | Missense Mutation (SNP) | VAF 58/200 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.783); catalogued as COSV101202006; called by muse, varscan2
- MUC16 | c.21962C>T p.S7321L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.683); catalogued as COSV101202008; called by muse, mutect2, varscan2
- MUC17 | c.11746C>T p.P3916S | Missense Mutation (SNP) | VAF 68/166 reads (41%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.615); catalogued as rs769183702, COSV60281022; called by muse, mutect2, varscan2
- MUC5AC | c.13930C>T p.P4644S | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT tolerated (0.2); catalogued as rs1488216947, COSV100611635; called by muse, mutect2, varscan2
1,634 further variants in this file (756 protein-altering or splice-affecting, 820 silent, 58 other) are not listed here.
